Somatic mutation profile of tumor specimen 0DVDU7 from CCDI case PBCKRP, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.0 years (4,027 days).
Specimen 0DVDU7: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5c237e88-8b4a-48a0-80d4-3713c0234053.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DVDUU (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f977f8a8-8148-4339-b83a-cbe112d51b04

The open-access MAF lists 6 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 5'UTR 1, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>G p.D816G | Missense Mutation (SNP) | VAF 247/581 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.965); catalogued as CM952169, COSV55386424, COSV55388612, COSV55408930; called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 27/854 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- CMYA5 | c.7118A>C p.K2373T | Missense Mutation (SNP) | VAF 95/373 reads (25%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.03); called by mutect2, varscan2
- FER1L6 | c.5042T>A p.L1681* | Nonsense Mutation (SNP) | VAF 40/620 reads (6%) | called by muse, mutect2
- SLC6A16 | c.1602T>C p.H534= | Silent (SNP) | VAF 36/307 reads (12%) | called by muse, mutect2, varscan2
- C3orf18 | c.-14C>G | 5'UTR (SNP) | VAF 18/208 reads (9%) | called by muse, mutect2
